Somatic mutation profile of tumor specimen TCGA-60-2709-01A (aliquot TCGA-60-2709-01A-21D-1817-08) from TCGA case TCGA-60-2709, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69.7 years (25,453 days).
Specimen TCGA-60-2709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2df3a07a-7198-438d-966c-d55ce170939c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2709-11A (Solid Tissue Normal), aliquot TCGA-60-2709-11A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a796568-8c63-4132-b0b6-5cd24901e9af

The open-access MAF lists 172 somatic variants for this specimen: 123 protein-altering or splice-affecting, 42 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 42, Nonsense Mutation 11, Frame Shift Del 4, RNA 4, Splice Site 2, Intron 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 24/111 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553487942, COSV67960075, COSV67960449, COSV67960680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 16/88 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV63672262; called by muse, mutect2
- AEBP1 | c.1544T>A p.V515E | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56256404; called by muse, mutect2, varscan2
- AICDA | c.391C>G p.R131G | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.189); catalogued as COSV57563767; called by muse, mutect2, varscan2
- AMOT | c.1942C>T p.Q648* (on ENST00000371959 / NM_001113490.1; = p.Q239* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV59061826; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2583A>T p.K861N | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV51843794; called by muse, mutect2, varscan2
- ANKRD26 | c.4401G>C p.R1467S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV65774672; called by muse, mutect2
- ANO3 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as COSV56785355; called by muse, mutect2, varscan2
- AP3B1 | c.595A>G p.K199E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1561487351, COSV54880455; called by muse, mutect2, varscan2
- ARAP3 | c.3208G>A p.G1070R | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53349638, COSV99500093; called by muse, mutect2
- ARHGAP32 | c.2996A>G p.Q999R (on ENST00000310343 / NM_001378025.1; = p.Q650R on NM_014715.4) | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV59845166; called by muse, mutect2
- ARSA | c.811G>C p.G271R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs747525975, COSV53350136; called by mutect2, varscan2
- ASNSD1 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as rs201596162, COSV53622999; called by muse, mutect2, varscan2
- ATM | c.8959G>T p.D2987Y | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs863224582, COSV53734480; ClinVar: uncertain significance; called by mutect2, varscan2
- AXDND1 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62640940; called by muse, mutect2
- BEND3 | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.037); catalogued as COSV64680562; called by muse, mutect2, varscan2
- C4orf51 | c.490G>T p.V164F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV71263975; called by muse, mutect2, varscan2
- CADPS | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV51872626, COSV99341566; called by muse, mutect2, varscan2
- CARD11 | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs142828146, COSV62753932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC33 | c.714G>T p.M238I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58349480; called by muse, mutect2, varscan2
- CDH10 | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV52574944; called by muse, mutect2, varscan2
- CDH8 | c.1549G>C p.V517L | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as rs753955851, COSV54856470; called by muse, mutect2, varscan2
- CILP | c.2810G>T p.W937L | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56022854; called by muse, mutect2
- CLDND1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.633); catalogued as rs755663467, COSV57858484; called by muse, mutect2, varscan2
- COL12A1 | c.7216G>A p.A2406T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59392299; called by muse, mutect2
- COL8A1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.9); catalogued as COSV53731444; called by muse, mutect2
- CSMD1 | c.1693G>T p.V565F (on ENST00000520002; = p.V564F on NM_033225.6) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV59300299, COSV59359418; called by muse, mutect2
- CSMD3 | c.2071C>A p.Q691K (on ENST00000297405 / NM_001363185.1; = p.Q587K on NM_052900.3) | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV52135525, COSV52174824; called by muse, mutect2
- CTNNA2 | c.2825A>T p.Q942L (on ENST00000402739 / NM_001282597.3; = p.Q894L on NM_004389.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV58142732; called by muse, mutect2, varscan2
- CTSV | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.088); catalogued as rs560756442, COSV52344066; called by muse, mutect2, varscan2
- DCAKD | c.314G>T p.R105L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60201948; called by muse, mutect2, varscan2
- DCST1 | c.733A>C p.K245Q | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs759735870, COSV55057570; called by muse, mutect2, varscan2
- DEPDC1 | c.1462A>G p.T488A | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1181910235, COSV63957858; called by muse, mutect2, varscan2
- DHX37 | c.100C>A p.L34M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV58133056; called by muse, mutect2, varscan2
- DIP2C | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55151233; called by muse, mutect2
- DPYSL2 | c.1472T>A p.L491Q | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.966); catalogued as COSV60782566; called by muse, mutect2
- ERICH3 | c.316G>T p.G106* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV58602614; called by muse, mutect2
- ESRRG | c.835A>G p.I279V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV63154796; called by muse, mutect2, varscan2
- EYS | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 36/70 reads (51%) | catalogued as COSV60980554; called by muse, varscan2
- F5 | c.3059T>C p.L1020P | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1196236335, COSV63122267; called by muse, mutect2, varscan2
- FAM135B | c.2675G>T p.R892M | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV52714134; called by muse, mutect2
- FAT3 | c.7735G>T p.G2579W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99964531; called by muse, mutect2, varscan2
- GALNT13 | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV67214259; called by muse, mutect2
- GDA | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52991579; called by muse, mutect2, varscan2
- GRIN2B | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74205311; called by muse, mutect2, varscan2
- HAS1 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55786828; called by muse, mutect2, varscan2
- HEATR1 | c.3499C>G p.P1167A | Missense Mutation (SNP) | VAF 44/426 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV63980175; called by muse, mutect2, varscan2
- HEATR5B | c.3333T>A p.N1111K | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV51850783; called by muse, mutect2, varscan2
- HERC1 | c.2951A>G p.H984R | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs1300389471, COSV71246829; called by muse, mutect2
- HMCN1 | c.6421G>T p.G2141C | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99627384; called by muse, mutect2
- HTR3E | c.1065C>G p.N355K (on ENST00000415389 / NM_001256613.1; = p.N370K on NM_182589.2) | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV58946205; called by muse, mutect2
- ITK | c.325+1G>T p.X109_splice | Splice Site (SNP) | VAF 21/129 reads (16%) | catalogued as COSV70061282; called by muse, mutect2, varscan2
- KAT2A | c.1627G>A p.V543I | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs782570663, COSV52425020; called by muse, mutect2
- KIF26B | c.3839C>G p.S1280C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100832953, COSV63639071; called by muse, mutect2
- KRT1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV52865697; called by muse, mutect2, varscan2
- LCT | c.2942C>A p.S981Y | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV51546214; called by muse, mutect2, varscan2
- LRRK2 | c.4415A>G p.E1472G | Missense Mutation (SNP) | VAF 39/251 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54148123; called by muse, mutect2, varscan2
- LRRTM1 | c.909G>C p.W303C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54439556, COSV54439824; called by muse, mutect2, varscan2
- MAGEA8 | c.478T>C p.C160R | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.532); catalogued as COSV54063856; called by muse, mutect2
- MAGEB2 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV66780477, COSV66781054; called by muse, mutect2, varscan2
- MCM9 | c.1061C>G p.P354R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57647528; called by muse, mutect2, varscan2
- MIGA1 | c.1061A>G p.Y354C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV66223203; called by muse, mutect2
- MUC16 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.51); catalogued as COSV67448120; called by muse, mutect2
- MUC16 | c.2648G>A p.R883K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.096); catalogued as COSV104431818, COSV67454777; called by muse, mutect2
- MUC5B | c.16749T>A p.C5583* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV71590915; called by muse, mutect2, varscan2
- MYH8 | c.1368G>T p.R456S | Missense Mutation (SNP) | VAF 38/260 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV67962136; called by muse, mutect2, varscan2
- NALCN | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51925372; called by muse, mutect2
- NCOA1 | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as COSV99945726; called by muse, mutect2
- NFXL1 | c.546A>G p.I182M | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.184); catalogued as COSV61198424; called by muse, mutect2, varscan2
- NOX4 | c.1337+2T>C p.X446_splice | Splice Site (SNP) | VAF 6/71 reads (8%) | catalogued as COSV54449565; called by muse, mutect2
- OR1C1 | c.796del p.H266Ifs*20 | Frame Shift Del (DEL) | VAF 15/98 reads (15%) | catalogued as rs1222904542, COSV101376291, COSV68715583; called by mutect2, pindel, varscan2
- OR2A5 | c.585C>G p.N195K | Missense Mutation (SNP) | VAF 29/290 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1401607346, COSV68738606; called by muse, mutect2
- OR5D18 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV61736614; called by muse, mutect2, varscan2
- OR5H2 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV62350252; called by muse, mutect2, varscan2
- OR5L1 | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV61732934, COSV61733238; called by muse, mutect2, varscan2
- PCDHB2 | c.1524C>G p.I508M | Missense Mutation (SNP) | VAF 25/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV50566727, COSV50574617; called by muse, mutect2, varscan2
- PCF11 | c.3630G>T p.M1210I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs759166122, COSV53529073; called by mutect2, varscan2
- PCNT | c.5101A>T p.N1701Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV64026564; called by muse, mutect2
- PHKB | c.2203A>G p.S735G | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs369776235; called by muse, mutect2, varscan2
- PIWIL3 | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177972, COSV59994401; called by muse, mutect2, varscan2
- PKD2L2 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV51795771; called by muse, mutect2, varscan2
- PLCXD3 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV60606787; called by muse, mutect2, varscan2
- PLEKHA2 | c.512G>T p.S171I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101173391; called by mutect2, varscan2
- PLXNA2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); catalogued as COSV65439086; called by muse, mutect2
- PRSS23 | c.553A>G p.K185E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as COSV54706474; called by muse, mutect2
- PSG7 | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 19/375 reads (5%) | catalogued as COSV68444671; called by muse, mutect2
- PTPRT | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 19/132 reads (14%) | catalogued as COSV61970078; called by muse, mutect2, varscan2
- PTPRZ1 | c.5946T>G p.Y1982* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as COSV66433381; called by muse, varscan2
- RAPGEF4 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV51382265; called by muse, mutect2, varscan2
- RBP4 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV65159793; called by muse, mutect2
- RELN | c.10328A>G p.H3443R | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.888); catalogued as COSV58992713; called by muse, mutect2, varscan2
- SIPA1L3 | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV55911117; called by muse, mutect2
- SLC5A8 | c.1545C>A p.N515K | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as rs768390941, COSV73310471; called by muse, mutect2
- SMPD4 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV60079247, COSV60080284, COSV60080323; called by muse, mutect2, varscan2
- SMYD1 | c.879C>G p.D293E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV70224743; called by muse, mutect2, varscan2
- SNX13 | c.1459A>G p.R487G | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.434); catalogued as COSV68064343; called by muse, mutect2
- SPTAN1 | c.1014A>T p.E338D | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.555); catalogued as COSV63986068; called by muse, mutect2, varscan2
- ST3GAL4 | c.339G>C p.Q113H (on ENST00000392669 / NM_001254758.1; = p.Q109H on NM_006278.3) | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.663); catalogued as COSV57106638; called by muse, mutect2, varscan2
- STAB2 | c.781A>T p.S261C | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs758931772, COSV66336684; called by muse, mutect2
- SYNE1 | c.11854G>T p.E3952* | Nonsense Mutation (SNP) | VAF 30/119 reads (25%) | catalogued as COSV54939993; called by muse, mutect2, varscan2
- SYTL2 | c.637A>T p.K213* | Nonsense Mutation (SNP) | VAF 9/110 reads (8%) | catalogued as COSV60357126; called by muse, mutect2
- SYTL5 | c.914C>A p.T305N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV52899495; called by muse, mutect2, varscan2
- TLN2 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60887508, COSV60892653; called by muse, mutect2, varscan2
- TMEM132B | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV54748737; called by muse, mutect2
- TMEM185A | c.483C>A p.D161E | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV57559156, COSV57560754; called by muse, mutect2
- TMF1 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1300918913, COSV68373908; called by muse, mutect2, varscan2
- TYW1 | c.104G>T p.W35L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.345); catalogued as COSV55887291; called by muse, mutect2
- TYW1 | c.105G>T p.W35C | Missense Mutation (SNP) | VAF 18/203 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.06); catalogued as COSV55887294; called by muse, mutect2
- USP6NL | c.1298G>T p.R433L | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99509499; called by muse, mutect2, varscan2
- VAMP7 | c.292C>G p.L98V | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1401961705, COSV52901443; called by muse, mutect2
- VWA5A | c.830A>T p.N277I | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63707430; called by muse, mutect2
- WDFY1 | c.738G>C p.Q246H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV51788609; called by muse, mutect2
- ZFHX4 | c.8395G>T p.D2799Y | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV50644659, COSV50702768; called by muse, mutect2
- ZIC1 | c.389G>C p.G130A | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV51552014, COSV51555391; called by muse, mutect2
- ZNF532 | c.1513G>C p.V505L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV100267106, COSV60172316; called by muse, mutect2
- ZNF536 | c.1678G>T p.D560Y | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV62821214; called by muse, mutect2
- ZNF99 | c.291A>T p.E97D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV68055260; called by muse, mutect2
- ADAMTS3 | c.3530del p.G1177Vfs*27 | Frame Shift Del (DEL) | VAF 35/162 reads (22%) | called by mutect2, pindel, varscan2
- DNAJC2 | c.1371del p.D457Efs*6 | Frame Shift Del (DEL) | VAF 13/128 reads (10%) | called by mutect2, pindel, varscan2
- FREM1 | c.429_437del p.V144_E146del | In Frame Del (DEL) | VAF 26/258 reads (10%) | called by mutect2, pindel
- GLYATL2 | c.781del p.A261Qfs*11 | Frame Shift Del (DEL) | VAF 10/103 reads (10%) | called by mutect2, pindel, varscan2
- TMEM132B | c.1345G>T p.G449W | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ABCA13 | c.4680T>C p.G1560= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as COSV70026985; called by muse, mutect2
- ACTN2 | c.504T>C p.Y168= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as rs756093904, COSV63973555; called by muse, mutect2, varscan2
- ATN1 | c.3276C>T p.I1092= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV57546573; called by muse, mutect2, varscan2
- ATP8B2 | c.2064G>T p.G688= (on ENST00000672630; = p.G655= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV59245391; called by muse, mutect2
- CADPS | c.1542C>A p.V514= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as COSV51872615; called by muse, mutect2, varscan2
- CAMSAP3 | c.3525G>A p.L1175= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs369401359, COSV50331918; called by muse, mutect2, varscan2
- CEBPG | c.255G>A p.Q85= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV52287230; called by muse, mutect2, varscan2
- CRCP | c.378A>G p.A126= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV58535182; called by muse, mutect2, varscan2
- CSF2RA | c.528G>A p.V176= | Silent (SNP) | VAF 43/330 reads (13%) | catalogued as COSV62624012; called by muse, mutect2, varscan2
- DHX57 | c.4116A>C p.G1372= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as COSV54883542; called by muse, mutect2
- EIF3B | c.822G>T p.T274= | Silent (SNP) | VAF 30/400 reads (8%) | catalogued as rs370385949; called by muse, mutect2
- ELMO1 | c.588G>T p.S196= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV60299505, COSV60302268; called by muse, mutect2, varscan2
- F13B | c.921G>A p.E307= | Silent (SNP) | VAF 22/162 reads (14%) | catalogued as COSV66373028; called by muse, mutect2, varscan2
- GPR37 | c.1473C>T p.N491= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV58256084; called by muse, mutect2
- GRIN2B | c.1872G>A p.K624= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as rs1220496922, COSV74205312; called by muse, mutect2, varscan2
- IGKV1D-42 | c.259A>C p.R87= | Silent (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- IL17REL | c.258C>A p.A86= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as COSV58007940; called by muse, mutect2, varscan2
- ISX | c.264C>T p.T88= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV58086007; called by muse, mutect2, varscan2
- ITGA8 | c.2757A>G p.A919= | Silent (SNP) | VAF 8/200 reads (4%) | catalogued as COSV65226651; called by muse, mutect2
- LILRA6 | c.936C>T p.P312= | Silent (SNP) | VAF 23/277 reads (8%) | catalogued as COSV54432361; called by muse, mutect2
- MRPS30 | c.1200T>C p.P400= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV50181601; called by muse, mutect2, varscan2
- MUC17 | c.7446C>T p.D2482= | Silent (SNP) | VAF 56/581 reads (10%) | catalogued as COSV60283714; called by muse, mutect2
- NANOS2 | c.330G>T p.T110= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV58024909, COSV58025812; called by muse, mutect2, varscan2
- NPC1 | c.2229T>A p.T743= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV52577416; called by muse, mutect2, varscan2
- OR11L1 | c.54G>A p.Q18= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs369061630; called by muse, mutect2, varscan2
- PCDH11X | c.3015G>T p.V1005= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as COSV53452837; called by muse, mutect2, varscan2
- PPFIA2 | c.477G>T p.R159= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs377309697, COSV100333546, COSV61047701; called by muse, mutect2, varscan2
- PRAMEF7 | c.1299G>T p.G433= | Silent (SNP) | VAF 14/226 reads (6%) | catalogued as COSV100435197; called by muse, mutect2
- PRDM9 | c.1542G>T p.V514= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV57004957, COSV57014674; called by muse, mutect2, varscan2
- PROP1 | c.63G>A p.L21= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV57644752; called by muse, varscan2
- RIOK1 | c.492C>A p.P164= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV99344685; called by muse, mutect2
- RPTOR | c.2304C>T p.T768= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV60805577; called by muse, mutect2, varscan2
- SCAF4 | c.1203A>G p.Q401= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs773644652, COSV54585295; called by muse, mutect2, varscan2
- SEMA5B | c.3120G>T p.T1040= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV99531393; called by muse, mutect2, varscan2
- SHANK3 | c.786C>T p.H262= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs374349808; called by muse, mutect2, varscan2
- SIGLEC14 | c.909C>A p.T303= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV55778443, COSV55778655; called by muse, mutect2, varscan2
- SIPA1L2 | c.1350C>T p.C450= | Silent (SNP) | VAF 35/288 reads (12%) | catalogued as COSV53386910; called by muse, mutect2, varscan2
- STK32B | c.214C>T p.L72= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1001379778, COSV51478501; called by muse, mutect2
- TBC1D26 | c.315G>T p.A105= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV101343663; called by muse, mutect2, varscan2
- TICAM1 | c.975C>T p.P325= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV50230436; called by muse, mutect2, varscan2
- TTC14 | c.2151T>C p.N717= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as COSV56010145; called by muse, mutect2
- ZBTB34 | c.1212C>T p.F404= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV59859597, COSV59859624; called by muse, mutect2, varscan2
- AC074085.2 | n.62C>A | RNA (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620362 G>A | 3'Flank (SNP) | VAF 119/899 reads (13%) | catalogued as COSV54084695; called by muse, mutect2, varscan2
- DDC | c.944+2361C>A | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100779204; called by muse, mutect2
- LDB3 | c.690-4755G>A | Intron (SNP) | VAF 42/225 reads (19%) | catalogued as COSV99554985; called by muse, mutect2, varscan2
- LINC02872 | n.360C>G | RNA (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- OR2U1P | n.387C>A | RNA (SNP) | VAF 39/222 reads (18%) | called by muse, mutect2, varscan2
- OR2U1P | n.386A>T | RNA (SNP) | VAF 39/219 reads (18%) | called by muse, mutect2, varscan2
